Somatic mutation profile of tumor specimen 0DVZ1N from CCDI case PBCNHH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.0 years (2,550 days).
Specimen 0DVZ1N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ccba92c-2a59-447a-8923-128693e0377e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVZ0P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab404108-452e-4e85-ac0f-21bd4e92ec47

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH8 | c.1912G>A p.V638M | Missense Mutation (SNP) | VAF 157/407 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs749935575, COSV54845694; called by muse, mutect2, varscan2
- DDX17 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99061223; called by muse, mutect2, varscan2
- MGAM | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 122/328 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374646574; called by muse, mutect2, varscan2
- NTNG1 | c.1453C>T p.R485C (on ENST00000370068 / NM_001113226.3; = p.R384C on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/472 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV64273714; called by muse, mutect2
- OR4S2 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100412705, COSV100412799; called by muse, mutect2, varscan2
- HSCB | c.504C>T p.I168= | Silent (SNP) | VAF 147/257 reads (57%) | catalogued as COSV99319722; called by muse, mutect2, varscan2
- SLC45A1 | c.198C>A p.T66= | Silent (SNP) | VAF 102/256 reads (40%) | called by muse, mutect2, varscan2
- SERPINA3 | c.917+51C>T | Intron (SNP) | VAF 161/412 reads (39%) | called by muse, mutect2, varscan2
- SVIL | c.4349-85G>A | Intron (SNP) | VAF 57/150 reads (38%) | catalogued as rs1343630847; called by muse, mutect2, varscan2
